Somatic mutation profile of tumor specimen TCGA-L5-A8NJ-01A (aliquot TCGA-L5-A8NJ-01A-11D-A36J-09) from TCGA case TCGA-L5-A8NJ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 77.2 years (28,200 days).
Specimen TCGA-L5-A8NJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ccce9a9-be4a-4235-85d8-b5eb7aee146f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NJ-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NJ-11A-11D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74c9896e-f2b9-4b8e-9e72-98516edd23a9

The open-access MAF lists 240 somatic variants for this specimen: 182 protein-altering or splice-affecting, 54 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 170, Silent 54, Frame Shift Del 4, Nonsense Mutation 3, Intron 2, RNA 2, Splice Site 2, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 16/20 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANO2 | c.2675C>T p.S892L (on ENST00000356134 / NM_001278597.3; = p.S896L on NM_001278596.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767967144, COSV59020201, COSV59035280; called by muse, mutect2, varscan2
- AP5M1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV55104422; called by muse, mutect2, varscan2
- ATMIN | c.367G>T p.D123Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs763472583; called by muse, mutect2, varscan2
- C11orf49 | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV99562609; called by muse, mutect2, varscan2
- CCDC39 | c.1640T>G p.L547R | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV56483277, COSV56491725; called by muse, mutect2, varscan2
- CD1E | c.458T>G p.I153S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100937040; called by muse, mutect2, varscan2
- CD79A | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs782467376, COSV55739664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH9 | c.2063T>G p.L688R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV50251341; called by muse, mutect2, varscan2
- CFH | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs754410335; called by muse, mutect2, varscan2
- CIART | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1553853923, COSV99290009; called by muse, mutect2, varscan2
- CLEC12A | c.442A>C p.S148R | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100429765, COSV58561507; called by muse, mutect2, varscan2
- CLEC7A | c.58T>G p.F20V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100021304; called by muse, mutect2, varscan2
- COG1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.288); catalogued as COSV55429806; called by muse, mutect2, varscan2
- CPT1B | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1430518843; called by muse, mutect2, varscan2
- CSMD2 | c.6955C>T p.R2319C | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768520749, COSV53932166; called by muse, mutect2, varscan2
- DENND2A | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as rs778989980; called by muse, mutect2, varscan2
- DNAH11 | c.8284A>G p.R2762G | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100178263; called by muse, mutect2, varscan2
- DSEL | c.1508A>G p.K503R | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59489806, COSV59492555; called by muse, mutect2, varscan2
- EGFLAM | c.998A>C p.K333T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100380735; called by muse, mutect2, varscan2
- ELMO1 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as COSV60293796; called by muse, mutect2, varscan2
- FAM131B | c.234del p.Q79Kfs*7 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as rs775219695; called by mutect2, pindel, varscan2
- FAM47C | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs868925278, COSV100792975, COSV63728294; called by muse, varscan2
- FLRT2 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.579); catalogued as COSV58141323; called by muse, mutect2, varscan2
- FOXA1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs141004703; called by muse, mutect2, varscan2
- FOXG1 | c.1384A>C p.S462R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.296); catalogued as COSV100486474, COSV104398698; called by muse, mutect2, varscan2
- FSCB | c.1037T>C p.L346P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100469835, COSV61219798; called by muse, mutect2
- GCNT4 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as rs149074938; called by muse, mutect2, varscan2
- GLYATL2 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54849987; called by muse, mutect2, varscan2
- GRIA2 | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52383728; called by muse, mutect2, varscan2
- GRIN3A | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs564083866; called by muse, mutect2, varscan2
- HBP1 | c.671A>T p.H224L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs768445935, COSV56019542; called by muse, mutect2, varscan2
- HSDL1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as rs763055432; called by muse, mutect2, varscan2
- HSPB3 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148535965; called by muse, mutect2, varscan2
- KCND3 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56176173; called by muse, mutect2, varscan2
- KCNQ3 | c.467T>A p.L156H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66464231; called by muse, mutect2, varscan2
- LAMA3 | c.8977C>G p.P2993A (on ENST00000313654 / NM_198129.4; = p.P1384A on NM_000227.6) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs756626587, COSV52533701; called by muse, varscan2
- LRRK2 | c.2609C>G p.S870C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV54148659; called by muse, varscan2
- MACF1 | c.10714C>G p.L3572V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs747824803; called by muse, varscan2
- MAGEB4 | c.823A>G p.R275G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV100974855; called by muse, mutect2, varscan2
- MAGEE1 | c.1652T>C p.L551P | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV100819199, COSV63910080, COSV63912447; called by muse, mutect2, varscan2
- MGAT3 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs754879346, COSV100361901; called by muse, mutect2, varscan2
- MROH2B | c.2846C>T p.A949V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as rs199545321, COSV68187019; called by muse, mutect2, varscan2
- MTUS2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2
- MUC16 | c.8090T>C p.L2697P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs780829182, COSV67450816; called by muse, mutect2, varscan2
- NBPF26 | c.1997C>T p.P666L (on ENST00000620612; = p.P404L on NM_001351372.1) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.859); catalogued as rs1553271564; called by mutect2, varscan2
- NECAB1 | c.69C>G p.H23Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1206683803; called by muse, mutect2, varscan2
- NLRP3 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99053285; called by muse, mutect2, varscan2
- NPR2 | c.3119G>A p.R1040Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs146546770, COSV52414453; called by muse, mutect2
- NTSR1 | c.916+1G>A p.X306_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as rs764083183, COSV65138117, COSV65138272; called by muse, mutect2, varscan2
- OR2A7 | c.839T>G p.F280C | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1160509827; called by muse, mutect2, varscan2
- OR5D13 | c.133T>G p.L45V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs112091941, COSV62335074; called by muse, mutect2, varscan2
- OR5L2 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65723654, COSV65724497; called by muse, mutect2, varscan2
- OR8H3 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV100538923; called by muse, mutect2, varscan2
- PAPPA | c.1265A>T p.E422V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV60287924; called by muse, mutect2, varscan2
- PCDH11X | c.3899C>T p.A1300V | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs768077489; called by muse, mutect2, varscan2
- PCDHB3 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.006); catalogued as rs782087248, COSV99166583; called by muse, mutect2, varscan2
- PDE4A | c.1600C>T p.R534C (on ENST00000380702 / NM_001111307.2; = p.R295C on NM_006202.3) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs951423867; called by muse, mutect2, varscan2
- POLE | c.1274A>T p.K425M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1512691; called by muse, mutect2, varscan2
- POTEE | c.2401C>A p.H801N | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as rs1427613844; called by muse, mutect2
- PRAMEF6 | c.386A>T p.K129M | Missense Mutation (SNP) | VAF 80/229 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1312287175; called by muse, mutect2, varscan2
- PSG6 | c.13T>C p.S5P | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV51837019; called by muse, mutect2, varscan2
- RALYL | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.452); catalogued as rs771106775; called by muse, mutect2, varscan2
- RESF1 | c.1501G>C p.D501H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV57019269; called by muse, varscan2
- RESF1 | c.1993G>A p.D665N | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100439988; called by muse, mutect2, varscan2
- REV3L | c.3242C>T p.S1081L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV104415785, COSV62619186, COSV62624248; called by muse, mutect2, varscan2
- SAMD9L | c.1979G>A p.C660Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs377186697; called by muse, mutect2, varscan2
- SCML4 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs555376188, COSV64635458; called by muse, mutect2, varscan2
- SCN5A | c.5633A>C p.K1878T (on ENST00000333535 / NM_198056.3; = p.K1877T on NM_000335.5) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61116275; called by muse, mutect2, varscan2
- SGCZ | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV65995245; called by muse, mutect2, varscan2
- SLC35F4 | c.377T>C p.V126A (on ENST00000339762 / NM_001352015.2; = p.V90A on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100333823; called by muse, mutect2, varscan2
- SNRPN | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57593843, COSV57596019; called by muse, mutect2, varscan2
- SNRPN | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100577858, COSV57596960; called by muse, mutect2, varscan2
- SNX14 | c.2302C>T p.R768C (on ENST00000314673 / NM_001350535.1; = p.R715C on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.719); catalogued as rs377525323; called by muse, mutect2, varscan2
- SOHLH2 | c.596A>C p.N199T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV58522887; called by muse, mutect2, varscan2
- SPANXN1 | c.158C>A p.A53E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs781875481, COSV65122946; called by muse, mutect2, varscan2
- SRBD1 | c.2894T>C p.L965P | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429195334; called by muse, mutect2, varscan2
- TEK | c.1813T>G p.L605V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV66228697; called by muse, mutect2, varscan2
- TPP2 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV65753910; called by muse, mutect2, varscan2
- TSPOAP1 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs772493918; called by muse, mutect2, varscan2
- UBTF | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); catalogued as rs372626678; called by muse, mutect2, varscan2
- UNC13C | c.2140T>G p.L714V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV52871597; called by muse, mutect2, varscan2
- VCL | c.2978G>A p.R993H (on ENST00000211998 / NM_014000.3; = p.R925H on NM_003373.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53008230; called by muse, mutect2, varscan2
- WDR72 | c.772T>G p.F258V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV100854104; called by muse, mutect2, varscan2
- WWOX | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1385421754, COSV101282823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZHX3 | c.2680G>A p.V894M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.871); catalogued as rs577583178; called by muse, mutect2, varscan2
- ZNF585B | c.2309G>C p.*770Sext*30 | Nonstop Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100459451; called by muse, mutect2, varscan2
- ZNF667 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV52638880; called by muse, mutect2, varscan2
- ACTG1 | c.433T>G p.S145A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ADGRB3 | c.1244C>A p.T415K | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADRA2C | c.304_310del p.T102Sfs*50 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- ALDH1A1 | c.26T>G p.L9* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- AMACR | c.355T>A p.L119I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANK3 | c.4493T>G p.F1498C | Missense Mutation (SNP) | VAF 109/189 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD26 | c.3533T>G p.L1178R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ANKRD30A | c.729T>G p.H243Q (on ENST00000611781; = p.H187Q on NM_052997.2) | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- APBA1 | c.1240T>G p.S414A | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- APOBEC1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AQR | c.3826G>A p.V1276I | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ASXL3 | c.2092T>G p.L698V | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- BEND2 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- BTN2A1 | c.555del p.A186Rfs*4 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | called by mutect2, pindel, varscan2
- BZW2 | c.387T>A p.F129L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3orf52 | c.542T>G p.M181R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CCDC184 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CDC42BPG | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.086); called by muse, mutect2
- CDH9 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLDN17 | c.211T>G p.L71V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CNNM2 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CUL5 | c.381dup p.S128Ifs*14 | Frame Shift Ins (INS) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- CXorf56 | c.320A>C p.K107T (on ENST00000536133 / NM_001170570.2; = p.K121T on NM_022101.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CYP7B1 | c.192A>T p.K64N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- DNAH3 | c.7427T>C p.I2476T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- DOCK2 | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- EPHA3 | c.218T>A p.V73D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ERBIN | c.2314A>G p.T772A | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EVI5 | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- FAM13C | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT2 | c.6658T>G p.F2220V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FEM1C | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FNBP1L | c.261A>C p.E87D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- GABRA2 | c.1254C>G p.D418E | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDF6 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GJA10 | c.504A>C p.E168D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLB1L3 | c.238T>C p.F80L | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HEY2 | c.999A>C p.E333D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- IDO1 | c.916T>G p.F306V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFIT3 | c.221T>C p.L74S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFT81 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITK | c.386A>T p.K129M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- KIF26A | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- KLF14 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KMT5B | c.757A>T p.M253L | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- LMO7 | c.1312T>A p.F438I (on ENST00000357063; = p.F168I on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRFN1 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MAP4K2 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDGA2 | c.2533A>G p.R845G (on ENST00000399232 / NM_001113498.2; = p.R547G on NM_182830.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MKRN3 | c.395T>G p.V132G | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSANTD4 | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MTERF3 | c.326T>G p.F109C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- NID2 | c.3173G>A p.S1058N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR13C2 | c.683T>G p.I228S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- OR13C9 | c.795A>T p.K265N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR4K14 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR5D16 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PCDHGB4 | c.346T>A p.F116I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHGB4 | c.1061T>C p.I354T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PCDHGB4 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PDE3A | c.2153T>G p.L718R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDE4B | c.806A>C p.N269T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PIP5KL1 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRR15 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PTPN9 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- RDX | c.1262T>G p.L421R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- RESF1 | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RNASEL | c.2014C>A p.H672N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ROBO2 | c.1223T>G p.V408G | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RXFP2 | c.2198C>G p.S733C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- RXFP3 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SALL1 | c.3842A>C p.N1281T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SF3A1 | c.1091_1093dup p.E364dup | In Frame Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, varscan2
- SI | c.4885T>G p.L1629V | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SLC24A4 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC25A47 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SSU72P8 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ST8SIA2 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 19/88 reads (22%) | PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- STAG2 | c.2920C>T p.H974Y | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- STEAP4 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STX11 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SYNE1 | c.11938T>G p.L3980V (on ENST00000367255 / NM_182961.4; = p.L3909V on NM_033071.3) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBL1XR1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM1 | c.3079A>C p.S1027R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TFPI2 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TG | c.1445A>T p.Q482L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- THOC2 | c.4275+2T>G p.X1425_splice | Splice Site (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- TMC4 | c.911G>T p.C304F (on ENST00000617472 / NM_001145303.3; = p.C298F on NM_144686.4) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- TRDJ3 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- TRHDE | c.1846C>G p.Q616E | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- TRPM1 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- TTN | c.56152A>C p.S18718R (on ENST00000591111; = p.S11294R on NM_003319.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- YTHDF3 | c.462_502del p.S154Rfs*9 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel
- ZNF454 | c.1565A>C p.K522T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ABHD2 | c.1092G>A p.E364= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- AGRN | c.235C>T p.L79= | Silent (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- ASTN1 | c.432G>A p.S144= | Silent (SNP) | VAF 50/68 reads (74%) | catalogued as rs778838558, COSV56067931; called by muse, mutect2, varscan2
- BMP5 | c.337A>C p.R113= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV63702491; called by muse, mutect2, varscan2
- CACNB2 | c.1321T>C p.L441= (on ENST00000324631 / NM_201596.3; = p.L386= on NM_000724.4) | Silent (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- CACNB2 | c.1596T>C p.S532= (on ENST00000324631 / NM_201596.3; = p.S477= on NM_000724.4) | Silent (SNP) | VAF 25/88 reads (28%) | called by muse, mutect2, varscan2
- CDH22 | c.705C>T p.R235= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1304242768, COSV64836497; called by muse, mutect2, varscan2
- CDH6 | c.2136C>G p.V712= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV54080023; called by muse, mutect2, varscan2
- CGN | c.3375C>T p.D1125= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as rs1407134514, COSV99642499; called by muse, mutect2
- CNTLN | c.3249A>G p.S1083= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as COSV99262683; called by muse, mutect2, varscan2
- CSPG4 | c.3666G>A p.T1222= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as rs765212087; called by muse, mutect2, varscan2
- DOCK2 | c.547T>C p.L183= | Silent (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- DPYS | c.1368G>A p.T456= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs35670436, COSV60910110; called by muse, mutect2, varscan2
- DSCAML1 | c.1869C>T p.D623= (on ENST00000321322; = p.D563= on NM_020693.4) | Silent (SNP) | VAF 33/54 reads (61%) | catalogued as rs575618156; called by muse, mutect2, varscan2
- DSE | c.1377T>G p.T459= | Silent (SNP) | VAF 33/37 reads (89%) | called by muse, mutect2, varscan2
- EDIL3 | c.456A>G p.R152= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- EHD3 | c.1527A>G p.K509= | Silent (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- EPHA1 | c.1363C>T p.L455= | Silent (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- EPHA6 | c.3174C>T p.V1058= | Silent (SNP) | VAF 76/160 reads (48%) | called by muse, mutect2, varscan2
- FAT3 | c.11235G>C p.G3745= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- FREM1 | c.1242C>G p.P414= | Silent (SNP) | VAF 26/62 reads (42%) | called by muse, varscan2
- HAND1 | c.267C>T p.G89= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs779893795; called by muse, varscan2
- HERC1 | c.4683C>T p.R1561= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- IRX1 | c.348T>C p.A116= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV57358402, COSV57358593, COSV57363094; called by muse, mutect2, varscan2
- KCNH6 | c.147C>T p.C49= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1333450393; called by muse, mutect2, varscan2
- LRRK2 | c.2532C>T p.I844= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs1234557218, COSV54160790; called by muse, varscan2
- MACF1 | c.17364T>A p.T5788= (on ENST00000372915; = p.T3830= on NM_012090.5) | Silent (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- MAN2C1 | c.156G>A p.E52= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1271862487, COSV51235756; called by muse, mutect2, varscan2
- METTL25 | c.435G>A p.Q145= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs983322165; called by muse, mutect2, varscan2
- MON1A | c.1800C>T p.N600= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs201362782, COSV56559832; called by muse, mutect2, varscan2
- NLRC4 | c.1200T>C p.G400= | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- NPR3 | c.63C>T p.A21= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs1031989391, COSV54085732; called by muse, mutect2, varscan2
- OR51B2 | c.445A>C p.R149= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1424045822; called by muse, mutect2, varscan2
- PARP9 | c.438G>A p.G146= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- PLOD3 | c.1218C>T p.L406= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs752044431, COSV99777997; called by muse, mutect2, varscan2
- PPP1R3C | c.937T>C p.L313= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1182436723, COSV53289166; called by muse, mutect2, varscan2
- RAPGEF2 | c.2775G>A p.K925= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- RHPN2 | c.1401C>T p.I467= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV54278401; called by muse, mutect2, varscan2
- RIF1 | c.624G>A p.E208= | Silent (SNP) | VAF 39/46 reads (85%) | catalogued as rs371693366; called by muse, mutect2, varscan2
- RNF133 | c.654T>C p.I218= | Silent (SNP) | VAF 36/55 reads (65%) | called by muse, mutect2, varscan2
- ROBO4 | c.2076G>A p.L692= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- SH3GL1 | c.1038C>T p.G346= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs760077070; called by muse, mutect2, varscan2
- SLCO1B1 | c.1977A>T p.S659= | Silent (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- ST6GALNAC5 | c.180G>A p.A60= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- TCF23 | c.540C>T p.T180= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2
- TEK | c.3336T>G p.T1112= | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, varscan2
- TGM6 | c.288T>G p.T96= | Silent (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- TRDN | c.1446A>G p.K482= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV62132361; called by muse, mutect2, varscan2
- TREM2 | c.552C>T p.L184= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- TSC2 | c.4029G>A p.E1343= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs752502287; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSHZ3 | c.1044C>A p.T348= | Silent (SNP) | VAF 18/26 reads (69%) | called by muse, mutect2, varscan2
- WFDC10A | c.12G>A p.Q4= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV58096558; called by muse, mutect2, varscan2
- YWHAE | c.42C>G p.A14= | Silent (SNP) | VAF 72/180 reads (40%) | called by muse, varscan2
- ZNF572 | c.1275C>A p.S425= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- MORF4 | n.647A>C | RNA (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- PRCP | c.168+15363G>A | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- TMEM99 | n.1070T>C | RNA (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- TTN | c.10303+1155A>G | Intron (SNP) | VAF 26/35 reads (74%) | called by muse, mutect2, varscan2
